Somatic mutation profile of tumor specimen TCGA-AJ-A3OL-01A (aliquot TCGA-AJ-A3OL-01A-11D-A228-09) from TCGA case TCGA-AJ-A3OL, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 55.1 years (20,115 days).
Specimen TCGA-AJ-A3OL-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8d5e1b61-12c8-4007-a461-e87a0a31ae35.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AJ-A3OL-10A (Blood Derived Normal), aliquot TCGA-AJ-A3OL-10A-01D-A22A-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/383c8b82-6f91-4c1e-ad4b-b417dea4b253

The open-access MAF lists 357 somatic variants for this specimen: 281 protein-altering or splice-affecting, 72 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 177, Frame Shift Del 79, Silent 72, Frame Shift Ins 15, Nonsense Mutation 5, In Frame Del 3, 3'Flank 1, Splice Site 1, Splice Region 1, Intron 1, 3'UTR 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BCOR | c.4376A>G p.N1459S (on ENST00000378444 / NM_001123385.2; = p.N1425S on NM_017745.6) | Missense Mutation (SNP) | VAF 34/71 reads (48%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.578); catalogued as rs199538037, COSV60698733; called by muse, mutect2, varscan2
- KCNQ2 | c.740C>T p.S247L | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.298); catalogued as rs74315392, CM034820, CM068334, COSV60436253; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- KMT2A | c.2318del p.P773Rfs*8 | Frame Shift Del (DEL) | VAF 9/17 reads (53%) | catalogued as rs782297546; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- KMT2D | c.9417del p.K3140Rfs*2 | Frame Shift Del (DEL) | VAF 7/19 reads (37%) | catalogued as rs1555190550; ClinVar: likely pathogenic; called by mutect2, pindel, varscan2
- PIK3CA | c.112C>T p.R38C | Missense Mutation (SNP) | VAF 11/21 reads (52%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs749415085, COSV55874617, COSV55892918, COSV55900319; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PIK3R2 | c.1117G>A p.G373R | Missense Mutation (SNP) | VAF 7/10 reads (70%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs587776934, CM126686, COSV55846573; ClinVar: pathogenic; called by muse, varscan2
- PTEN | c.408T>A p.C136* | Nonsense Mutation (SNP) | VAF 64/68 reads (94%) | hotspot (GDC flag); catalogued as COSV64294647, COSV64306028; called by muse, mutect2, varscan2
- AAR2 | c.38G>A p.R13H | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as rs140129195, COSV57924635; called by muse, mutect2, varscan2
- ABCC12 | c.1843C>T p.R615C | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs146005796; called by muse, mutect2, varscan2
- ABCD2 | c.797C>T p.A266V | Missense Mutation (SNP) | VAF 21/42 reads (50%) | SIFT tolerated (0.35); PolyPhen benign (0.038); catalogued as COSV100429187; called by muse, mutect2, varscan2
- ACAN | c.6841A>G p.R2281G | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT tolerated (0.19); PolyPhen benign (0.009); catalogued as COSV100717224; called by muse, mutect2, varscan2
- ADAM8 | c.1351G>A p.G451S | Missense Mutation (SNP) | VAF 37/75 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs767160793, COSV101291616, COSV101291761; called by muse, mutect2, varscan2
- ADAM9 | c.530T>G p.V177G | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as COSV101122231; called by muse, mutect2
- ADAMTSL1 | c.2498C>T p.P833L | Missense Mutation (SNP) | VAF 23/42 reads (55%) | SIFT tolerated (0.7); PolyPhen benign (0.015); catalogued as rs750448171, COSV101001403; called by muse, mutect2, varscan2
- ADRA2A | c.1258C>T p.R420C | Missense Mutation (SNP) | VAF 17/29 reads (59%) | SIFT deleterious (0.01); PolyPhen benign (0.059); catalogued as COSV99701490; called by muse, mutect2, varscan2
- AK3 | c.436A>C p.K146Q | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT tolerated (0.27); PolyPhen benign (0.106); catalogued as COSV100729393; called by muse, mutect2, varscan2
- AKAP12 | c.3550G>T p.G1184C | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT deleterious (0.02); PolyPhen benign (0.319); catalogued as COSV99482575; called by muse, mutect2, varscan2
- ANGEL1 | c.259G>A p.A87T | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.453); catalogued as rs769296198, COSV99200326; called by muse, mutect2, varscan2
- ANKRD46 | c.465T>G p.S155R | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.778); catalogued as COSV100169914; called by muse, mutect2, varscan2
- AQR | c.3893G>C p.R1298T | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99333325; called by muse, mutect2, varscan2
- ARHGEF37 | c.896C>G p.A299G | Missense Mutation (SNP) | VAF 25/58 reads (43%) | SIFT tolerated (0.22); PolyPhen benign (0.017); catalogued as COSV100381945, COSV61368196; called by muse, mutect2, varscan2
- ART1 | c.735del p.F246Lfs*6 | Frame Shift Del (DEL) | VAF 8/27 reads (30%) | catalogued as rs762428866, COSV99167258; called by mutect2, pindel, varscan2
- ASAP3 | c.1207G>A p.G403R | Missense Mutation (SNP) | VAF 18/30 reads (60%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.9); catalogued as rs1297800172, COSV100369228; called by muse, mutect2, varscan2
- ASPSCR1 | c.755del p.L252Rfs*11 | Frame Shift Del (DEL) | VAF 14/25 reads (56%) | catalogued as rs754464527, COSV60727771; called by mutect2, varscan2
- ATG9B | c.2336C>T p.P779L | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT tolerated (0.11); PolyPhen benign (0.091); catalogued as rs756553369, COSV99871276; called by muse, mutect2, varscan2
- ATP10B | c.2621C>T p.A874V | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.749); catalogued as COSV100514286; called by muse, mutect2, varscan2
- ATRN | c.518G>A p.R173H | Missense Mutation (SNP) | VAF 25/68 reads (37%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.459); catalogued as rs535151003, COSV99496705; called by muse, mutect2, varscan2
- AWAT1 | c.838del p.E280Sfs*51 | Frame Shift Del (DEL) | VAF 11/26 reads (42%) | catalogued as rs778111564; called by mutect2, pindel, varscan2
- AXIN2 | c.1804G>A p.G602R | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT tolerated (0.55); PolyPhen benign (0.264); catalogued as rs1203434475, COSV100197038, COSV61055438; called by muse, mutect2, varscan2
- B4GALNT3 | c.1867G>A p.E623K | Missense Mutation (SNP) | VAF 26/50 reads (52%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.566); catalogued as rs531502676, COSV99842554; called by muse, mutect2, varscan2
- BCL11A | c.832G>A p.A278T (on ENST00000335712 / NM_001365609.1; = p.A312T on NM_018014.4) | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT tolerated (0.28); PolyPhen benign (0.29); catalogued as COSV100184971; called by muse, mutect2, varscan2
- BCORL1 | c.5042del p.P1681Qfs*20 | Frame Shift Del (DEL) | VAF 13/29 reads (45%) | catalogued as rs768244116; called by mutect2, pindel, varscan2
- BMP10 | c.713G>A p.R238Q | Missense Mutation (SNP) | VAF 20/36 reads (56%) | SIFT tolerated (0.57); PolyPhen benign (0.001); catalogued as rs778579679, COSV99770295; called by muse, mutect2, varscan2
- CAAP1 | c.571del p.I191Ffs*2 | Frame Shift Del (DEL) | VAF 14/30 reads (47%) | catalogued as rs754356646, COSV61700397; called by mutect2, varscan2
- CACNA1A | c.4483G>A p.V1495I | Missense Mutation (SNP) | VAF 30/56 reads (54%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.758); catalogued as rs1211294190, COSV100801244; called by muse, mutect2, varscan2
- CACNA1H | c.6964C>T p.R2322W | Missense Mutation (SNP) | VAF 19/34 reads (56%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as rs987712309, COSV52353215; called by muse, mutect2, varscan2
- CACNG3 | c.937A>G p.T313A | Missense Mutation (SNP) | VAF 8/11 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99135474; called by muse, mutect2
- CAMTA1 | c.2191G>A p.G731S | Missense Mutation (SNP) | VAF 13/20 reads (65%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as rs146328777; called by muse, mutect2, varscan2
- CAPRIN2 | c.2689G>A p.V897M | Missense Mutation (SNP) | VAF 25/39 reads (64%) | SIFT tolerated (0.1); PolyPhen benign (0.419); catalogued as rs780524389, COSV99195427; called by muse, mutect2, varscan2
- CARNS1 | c.208G>A p.A70T | Missense Mutation (SNP) | VAF 16/28 reads (57%) | SIFT tolerated (0.16); PolyPhen benign (0.122); catalogued as rs775422380, COSV100321794; called by muse, mutect2, varscan2
- CASZ1 | c.1777G>A p.E593K | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs1431332439, COSV100680832, COSV100682104; called by muse, mutect2, varscan2
- CATSPERD | c.1264T>C p.S422P | Missense Mutation (SNP) | VAF 3/24 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.018); catalogued as COSV100486681; called by muse, mutect2
- CCDC102B | c.468G>T p.Q156H | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (0.58); PolyPhen possibly damaging (0.639); catalogued as COSV60138267, COSV60140705; called by muse, mutect2, varscan2
- CCDC173 | c.524G>A p.R175Q | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs750324427, COSV69573527; called by muse, mutect2
- CCDC174 | c.496G>A p.V166M | Missense Mutation (SNP) | VAF 42/88 reads (48%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs374255925; called by muse, mutect2, varscan2
- CCDC18 | c.774del p.V259Wfs*15 | Frame Shift Del (DEL) | VAF 16/36 reads (44%) | catalogued as rs746565576, COSV58142470; called by mutect2, varscan2
- CCDC9B | c.1193G>T p.G398V | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.648); catalogued as COSV101233479; called by muse, mutect2, varscan2
- CD82 | c.775G>A p.E259K | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.799); catalogued as rs766230830, COSV99907403; called by muse, mutect2
- CDC42EP1 | c.182C>T p.T61M | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs756627353, COSV99312377; called by muse, mutect2, varscan2
- CDH9 | c.1699C>T p.P567S | Missense Mutation (SNP) | VAF 17/26 reads (65%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV99142015, COSV99150769; called by muse, mutect2, varscan2
- CDX1 | c.496C>T p.R166C | Missense Mutation (SNP) | VAF 21/41 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs771897143, COSV51567414, COSV99199299; called by muse, mutect2, varscan2
- CEP120 | c.2950G>A p.A984T | Missense Mutation (SNP) | VAF 18/33 reads (55%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0); catalogued as COSV100070875; called by muse, mutect2, varscan2
- CFAP65 | c.1852-2A>C p.X618_splice | Splice Site (SNP) | VAF 11/34 reads (32%) | catalogued as COSV100444719; called by muse, mutect2, varscan2
- CHAD | c.1034G>A p.S345N | Missense Mutation (SNP) | VAF 36/78 reads (46%) | SIFT tolerated (0.31); PolyPhen benign (0.014); catalogued as COSV99366065; called by muse, mutect2, varscan2
- CHM | c.1920G>T p.K640N | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0.013); catalogued as rs748006115, COSV100753053; called by muse, mutect2, varscan2
- CIDEA | c.158G>A p.S53N | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT tolerated (0.38); PolyPhen benign (0.017); catalogued as rs879100352, COSV100254903; called by muse, mutect2, varscan2
- CILP | c.2006C>T p.T669I | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.08); catalogued as rs780080727, COSV99972890; called by muse, mutect2, varscan2
- CKAP5 | c.6013T>C p.S2005P (on ENST00000529230 / NM_001008938.4; = p.S1945P on NM_014756.3) | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV100319364; called by muse, mutect2, varscan2
- COL24A1 | c.3299C>T p.P1100L | Missense Mutation (SNP) | VAF 22/37 reads (59%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.688); catalogued as rs765411309, COSV100992967; called by muse, mutect2, varscan2
- COL9A1 | c.2606G>A p.G869D | Missense Mutation (SNP) | VAF 11/15 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100294168; called by muse, mutect2, varscan2
- CREB3L1 | c.986A>G p.N329S | Missense Mutation (SNP) | VAF 17/34 reads (50%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV99914851; called by muse, mutect2, varscan2
- CRTC1 | c.1713del p.S572Afs*6 | Frame Shift Del (DEL) | VAF 13/24 reads (54%) | catalogued as rs769538822; called by mutect2, varscan2
- CYP2W1 | c.205G>A p.V69M | Missense Mutation (SNP) | VAF 9/15 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs535558848, COSV100417118; called by muse, mutect2, varscan2
- DAZAP1 | c.770del p.P257Rfs*78 | Frame Shift Del (DEL) | VAF 14/20 reads (70%) | catalogued as COSV99245498; called by mutect2, varscan2
- DBH | c.274C>T p.R92C | Missense Mutation (SNP) | VAF 21/38 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs141137998; called by muse, mutect2, varscan2
- DCAF1 | c.2711G>A p.R904H | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as COSV60046180; called by muse, mutect2, varscan2
- DCPS | c.539T>G p.L180R | Missense Mutation (SNP) | VAF 23/49 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99703363; called by muse, mutect2, varscan2
- DGAT1 | c.256C>A p.R86S | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100183942, COSV60048815; called by muse, mutect2, varscan2
- DGLUCY | c.1674G>A p.W558* | Nonsense Mutation (SNP) | VAF 26/56 reads (46%) | catalogued as COSV99824055; called by muse, mutect2, varscan2
- DMXL2 | c.4279C>A p.P1427T | Missense Mutation (SNP) | VAF 3/36 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV51840769, COSV99196004; called by muse, mutect2
- DNA2 | c.2335del p.S779Hfs*6 | Frame Shift Del (DEL) | VAF 14/32 reads (44%) | catalogued as rs745893364; called by mutect2, varscan2
- DOHH | c.208G>A p.A70T | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs753023201, COSV51744452; called by muse, mutect2, varscan2
- DOK5 | c.487T>C p.Y163H | Missense Mutation (SNP) | VAF 35/89 reads (39%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV99373336; called by muse, mutect2, varscan2
- DOLK | c.1154G>A p.G385D | Missense Mutation (SNP) | VAF 15/26 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1483513507, COSV100454974; called by muse, mutect2, varscan2
- DYNC1I1 | c.346G>A p.D116N | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT tolerated (0.13); PolyPhen benign (0.439); catalogued as rs765322548, COSV61456229; called by muse, mutect2, varscan2
- E2F5 | c.930C>T p.D310= | Splice Region (SNP) | VAF 17/42 reads (40%) | catalogued as rs755426627, COSV99809321; called by muse, mutect2, varscan2
- EIF2B3 | c.450del p.A151Qfs*57 | Frame Shift Del (DEL) | VAF 24/40 reads (60%) | catalogued as rs748937918; called by mutect2, varscan2
- ETV4 | c.496T>C p.S166P | Missense Mutation (SNP) | VAF 23/49 reads (47%) | SIFT tolerated (0.42); PolyPhen benign (0.007); catalogued as COSV100081571; called by muse, mutect2, varscan2
- FAHD2A | c.842del p.P281Qfs*26 | Frame Shift Del (DEL) | VAF 16/32 reads (50%) | catalogued as rs766589051; called by mutect2, pindel, varscan2
- FAM193A | c.2612G>A p.R871Q | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61190907; called by muse, mutect2
- FBLN7 | c.779G>A p.R260Q | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated (0.58); PolyPhen benign (0.001); catalogued as rs569662326, COSV99734721; called by muse, mutect2, varscan2
- FGA | c.668T>C p.L223P | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.433); catalogued as COSV100120075; called by muse, mutect2, varscan2
- FHOD1 | c.275G>A p.R92Q | Missense Mutation (SNP) | VAF 12/18 reads (67%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.616); catalogued as rs757610175, COSV99263886; called by muse, mutect2, varscan2
- FLNA | c.2953G>A p.V985I | Missense Mutation (SNP) | VAF 25/49 reads (51%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.97); catalogued as rs781884864, COSV61047958; called by muse, mutect2, varscan2
- FMR1NB | c.64G>A p.A22T | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.961); catalogued as rs1569546486, COSV100975486; called by muse, mutect2, varscan2
- FUBP1 | c.30del p.S11Lfs*43 | Frame Shift Del (DEL) | VAF 24/58 reads (41%) | catalogued as rs908264837; called by mutect2, pindel, varscan2
- FYB1 | c.1358A>C p.E453A | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT tolerated (0.26); PolyPhen benign (0.3); catalogued as COSV100684987; called by muse, mutect2, varscan2
- GABRA5 | c.269C>T p.T90M | Missense Mutation (SNP) | VAF 15/22 reads (68%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.954); catalogued as COSV59477279; called by muse, mutect2, varscan2
- GABRA6 | c.250C>T p.R84C | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs754862222, COSV50877427; called by muse, mutect2
- GALNT9 | c.1135G>A p.E379K (on ENST00000328957 / NM_001122636.2; = p.E13K on NM_021808.3) | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.18); catalogued as rs751954230, COSV61095949; called by muse, mutect2, varscan2
- GARNL3 | c.2321G>A p.R774H | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1368892230, COSV100149990; called by muse, mutect2, varscan2
- GARRE1 | c.201G>A p.M67I | Missense Mutation (SNP) | VAF 9/13 reads (69%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.003); catalogued as rs1483339918, COSV100209090; called by muse, mutect2, varscan2
- GLYR1 | c.1007C>T p.A336V | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.662); catalogued as rs751687606, COSV58926459; called by muse, mutect2, varscan2
- GOLGA2 | c.1548G>A p.M516I | Missense Mutation (SNP) | VAF 27/63 reads (43%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.64); catalogued as rs775850583, COSV101363074; called by muse, mutect2, varscan2
- GUF1 | c.1934del p.K645Sfs*2 | Frame Shift Del (DEL) | VAF 10/18 reads (56%) | catalogued as COSV54945907; called by mutect2, varscan2
- IARS1 | c.3089C>T p.T1030I | Missense Mutation (SNP) | VAF 21/45 reads (47%) | SIFT tolerated (0.15); PolyPhen benign (0.028); catalogued as COSV100986676, COSV65113577; called by muse, mutect2, varscan2
- INPPL1 | c.3466del p.R1156Gfs*46 | Frame Shift Del (DEL) | VAF 9/15 reads (60%) | catalogued as rs760925109; called by mutect2, pindel, varscan2
- IQGAP3 | c.2260T>C p.S754P | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.637); catalogued as COSV100752083; called by muse, mutect2, varscan2
- ISLR2 | c.2164C>T p.R722W | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100679425; called by muse, varscan2
- KALRN | c.4068G>T p.E1356D | Missense Mutation (SNP) | VAF 22/40 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV99562447; called by muse, mutect2, varscan2
- KBTBD4 | c.1156del p.E386Rfs*27 | Frame Shift Del (DEL) | VAF 4/37 reads (11%) | catalogued as rs756343868; called by pindel, varscan2
- KCNF1 | c.1115G>A p.G372D | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99705572; called by muse, mutect2, varscan2
- KIF17 | c.1113C>A p.S371R | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT tolerated (0.17); PolyPhen benign (0.011); catalogued as COSV99928626; called by muse, mutect2, varscan2
- KMT2B | c.5168T>A p.L1723H | Missense Mutation (SNP) | VAF 34/65 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99718955; called by muse, mutect2
- KRT13 | c.602G>A p.R201H | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.493); catalogued as rs781291691, COSV55838986; called by muse, mutect2, varscan2
- KRTAP2-4 | c.368G>A p.C123Y | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs776346638, COSV101224322; called by muse, mutect2, varscan2
- LBX1 | c.562A>G p.K188E | Missense Mutation (SNP) | VAF 16/31 reads (52%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.574); catalogued as COSV100929908; called by muse, mutect2, varscan2
- LDB2 | c.928G>A p.G310S | Missense Mutation (SNP) | VAF 20/34 reads (59%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.931); catalogued as COSV100452740; called by muse, mutect2, varscan2
- LMOD1 | c.1276C>T p.R426* | Nonsense Mutation (SNP) | VAF 18/49 reads (37%) | catalogued as COSV100939095; called by muse, mutect2, varscan2
- LVRN | c.62G>T p.G21V | Missense Mutation (SNP) | VAF 6/9 reads (67%) | SIFT tolerated (0.65); PolyPhen benign (0.04); catalogued as COSV100773351; called by muse, mutect2, varscan2
- LY75 | c.2531A>G p.H844R | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT tolerated (0.08); PolyPhen benign (0.055); catalogued as COSV99716095; called by muse, mutect2, varscan2
- MAN2A1 | c.1916del p.N639Ifs*2 | Frame Shift Del (DEL) | VAF 8/30 reads (27%) | catalogued as rs758700583; called by mutect2, pindel, varscan2
- MAP3K6 | c.649G>T p.V217L | Missense Mutation (SNP) | VAF 7/10 reads (70%) | SIFT tolerated (0.06); PolyPhen benign (0.085); catalogued as COSV99585248; called by muse, mutect2, varscan2
- MBD6 | c.2345del p.G782Efs*13 | Frame Shift Del (DEL) | VAF 11/27 reads (41%) | catalogued as rs746267361; called by mutect2, varscan2
- MGAT1 | c.539A>G p.Q180R | Missense Mutation (SNP) | VAF 6/13 reads (46%) | PolyPhen benign (0.049); catalogued as rs1326260639, COSV100286539; called by muse, mutect2, varscan2
- MINAR1 | c.2104del p.S702Afs*11 | Frame Shift Del (DEL) | VAF 10/20 reads (50%) | catalogued as rs748072217, COSV59581461; called by mutect2, varscan2
- MINK1 | c.1952G>A p.S651N | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV100767029; called by muse, mutect2, varscan2
- MSANTD1 | c.265C>T p.R89C | Missense Mutation (SNP) | VAF 18/26 reads (69%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.877); catalogued as rs759178515, COSV101433570; called by muse, mutect2, varscan2
- MTNR1A | c.556G>A p.A186T | Missense Mutation (SNP) | VAF 18/23 reads (78%) | SIFT tolerated (0.39); PolyPhen benign (0.066); catalogued as rs772092531, COSV100208130, COSV56155845; called by muse, mutect2, varscan2
- MYOM2 | c.2008G>A p.V670M | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.784); catalogued as rs367658424, COSV100036804, COSV100038801; called by muse, mutect2, varscan2
- NDUFC2 | c.207del p.F69Lfs*7 | Frame Shift Del (DEL) | VAF 5/13 reads (38%) | catalogued as rs747914168; called by mutect2, varscan2
- NIPBL | c.8326del p.I2776Lfs*3 | Frame Shift Del (DEL) | VAF 13/29 reads (45%) | catalogued as rs1157335847; called by mutect2, pindel, varscan2
- NLRX1 | c.890G>A p.R297H | Missense Mutation (SNP) | VAF 14/25 reads (56%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.865); catalogued as rs750925908, COSV52702114; called by muse, mutect2, varscan2
- NOTCH3 | c.2459G>A p.C820Y | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99656097; called by muse, mutect2, varscan2
- NPR2 | c.130C>T p.R44W | Missense Mutation (SNP) | VAF 53/93 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100709329; called by muse, mutect2, varscan2
- NR1H3 | c.643G>A p.E215K | Missense Mutation (SNP) | VAF 12/20 reads (60%) | SIFT tolerated (0.3); PolyPhen benign (0.007); catalogued as rs535109345, COSV101269723; called by muse, mutect2, varscan2
- NSG1 | c.253G>A p.V85M | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.866); catalogued as rs935161247, COSV67574747; called by muse, mutect2, varscan2
- NSMAF | c.1585G>T p.V529L | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.067); catalogued as COSV99232411; called by muse, mutect2
- NTRK3 | c.606G>A p.M202I | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0.36); catalogued as COSV100445742; called by muse, mutect2, varscan2
- OR10A3 | c.350C>T p.A117V | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated (0.77); PolyPhen benign (0.007); catalogued as rs777277922, COSV62459854; called by muse, mutect2, varscan2
- OR14C36 | c.315del p.F105Lfs*28 | Frame Shift Del (DEL) | VAF 40/138 reads (29%) | catalogued as rs761899382; called by mutect2, varscan2
- OR2T2 | c.578C>T p.T193M | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs757714944, COSV100737721, COSV61617901; called by muse, mutect2, varscan2
- OR5A2 | c.509G>A p.C170Y | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100119681; called by muse, mutect2, varscan2
- ORAI2 | c.427C>T p.H143Y | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100709854; called by muse, mutect2, varscan2
- OTUD6A | c.634C>T p.R212C | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.862); catalogued as rs370977424, COSV57972519; called by muse, mutect2, varscan2
- PAGE5 | c.85C>A p.Q29K | Missense Mutation (SNP) | VAF 21/40 reads (53%) | SIFT tolerated (0.58); PolyPhen benign (0.022); catalogued as COSV99215704; called by muse, mutect2, varscan2
- PAPPA | c.4335T>G p.S1445R | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.773); catalogued as COSV100073045; called by muse, mutect2, varscan2
- PCDHA2 | c.2365T>C p.S789P | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0); catalogued as COSV100973630; called by muse, mutect2, varscan2
- PCDHA8 | c.1078C>T p.R360C | Missense Mutation (SNP) | VAF 24/42 reads (57%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.947); catalogued as rs781796924, COSV65335014; called by muse, mutect2, varscan2
- PCDHB8 | c.1351G>A p.A451T | Missense Mutation (SNP) | VAF 46/103 reads (45%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.007); catalogued as rs1414157434, COSV99175991; called by muse, mutect2, varscan2
- PCDHGB6 | c.1114C>T p.R372W | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.903); catalogued as rs114361948, COSV54027199; called by muse, mutect2, varscan2
- PCNX2 | c.2233G>A p.V745I | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV99266301; called by muse, mutect2, varscan2
- PDLIM4 | c.601G>A p.V201M | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.014); catalogued as rs778997358, COSV99516736; called by muse, mutect2, varscan2
- PLD2 | c.1037C>T p.A346V | Missense Mutation (SNP) | VAF 19/38 reads (50%) | SIFT deleterious (0.04); PolyPhen benign (0.23); catalogued as COSV99562074; called by muse, mutect2, varscan2
- PLEKHA5 | c.2995del p.T999Lfs*17 | Frame Shift Del (DEL) | VAF 6/14 reads (43%) | catalogued as rs759995048, COSV54701412; called by mutect2, varscan2
- PLK2 | c.1004del p.L335Cfs*68 | Frame Shift Del (DEL) | VAF 8/17 reads (47%) | catalogued as rs772701630; called by mutect2, varscan2
- PPP1R10 | c.2084del p.G695Vfs*222 | Frame Shift Del (DEL) | VAF 11/27 reads (41%) | catalogued as rs760405117; called by mutect2, pindel, varscan2
- PRICKLE2 | c.1208C>T p.T403M (on ENST00000295902; = p.T347M on NM_198859.4) | Missense Mutation (SNP) | VAF 12/21 reads (57%) | SIFT deleterious (0.03); PolyPhen benign (0.197); catalogued as rs375755312; called by muse, mutect2, varscan2
- PRLHR | c.581C>T p.A194V | Missense Mutation (SNP) | VAF 9/10 reads (90%) | SIFT deleterious (0.01); PolyPhen benign (0.383); catalogued as COSV53303431; called by muse, mutect2, varscan2
- PRPH2 | c.934G>A p.V312M | Missense Mutation (SNP) | VAF 15/25 reads (60%) | SIFT deleterious (0.03); PolyPhen benign (0.057); catalogued as rs771015384, COSV57838020; called by muse, mutect2
- PRR12 | c.3292G>C p.E1098Q (on ENST00000615927; = p.E1919Q on NM_020719.3) | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.977); catalogued as COSV101330584, COSV101330597; called by muse, mutect2, varscan2
- PRRG1 | c.401del p.P134Hfs*19 | Frame Shift Del (DEL) | VAF 18/39 reads (46%) | catalogued as rs781858060; called by mutect2, varscan2
- PSMC2 | c.1144G>A p.G382S | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99485176; called by muse, mutect2, varscan2
- PTK6 | c.109G>A p.V37M | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs757318592, COSV99420340; called by muse, mutect2, varscan2
- PUDP | c.262A>G p.T88A | Missense Mutation (SNP) | VAF 19/38 reads (50%) | SIFT tolerated (0.12); PolyPhen benign (0.062); catalogued as COSV101127813; called by muse, mutect2, varscan2
- RAB8A | c.38T>C p.L13P | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV99959694; called by muse, mutect2, varscan2
- RAD54L2 | c.2386C>T p.R796W | Missense Mutation (SNP) | VAF 15/28 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs542809426, COSV99620819; called by muse, mutect2, varscan2
- RAET1G | c.140C>T p.P47L | Missense Mutation (SNP) | VAF 38/92 reads (41%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.636); catalogued as COSV100951640; called by muse, mutect2, varscan2
- RB1 | c.1959del p.V654Cfs*4 | Frame Shift Del (DEL) | VAF 12/28 reads (43%) | catalogued as CM1110478, COSV57298520; called by mutect2, pindel, varscan2
- RBM43 | c.971T>C p.L324P | Missense Mutation (SNP) | VAF 25/48 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100508500; called by muse, mutect2, varscan2
- RBSN | c.329G>A p.R110Q | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1248707557, COSV99515052; called by muse, mutect2, varscan2
- RNF111 | c.2311C>T p.R771C | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV62083715; called by muse, mutect2, varscan2
- RNF168 | c.694A>G p.K232E | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.162); catalogued as COSV100534862; called by muse, mutect2, varscan2
- RXFP3 | c.416C>T p.A139V | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57504071; called by muse, mutect2, varscan2
- S100A3 | c.294del p.C99Afs*54 | Frame Shift Del (DEL) | VAF 15/62 reads (24%) | catalogued as rs1279717323; called by mutect2, pindel, varscan2
- S100A7L2 | c.241del p.D81Ifs*2 | Frame Shift Del (DEL) | VAF 17/49 reads (35%) | catalogued as rs1184903636, COSV64194825; called by mutect2, pindel, varscan2
- SCML2 | c.1837G>A p.A613T | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT tolerated (0.7); PolyPhen benign (0.115); catalogued as COSV99318618; called by muse, mutect2, varscan2
- SCN5A | c.5590del p.E1864Sfs*8 (on ENST00000333535 / NM_198056.3; = p.E1863Sfs*8 on NM_000335.5) | Frame Shift Del (DEL) | VAF 26/76 reads (34%) | catalogued as COSV61117049; called by mutect2, pindel, varscan2
- SDK2 | c.4612C>T p.R1538W | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.803); catalogued as rs199630308, COSV66187059; called by muse, mutect2, varscan2
- SEMA4C | c.293A>G p.E98G | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.392); catalogued as COSV100560758; called by muse, mutect2, varscan2
- SGIP1 | c.281G>A p.G94D | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.96); catalogued as COSV99390654; called by muse, mutect2, varscan2
- SH2D3A | c.1696G>A p.G566S | Missense Mutation (SNP) | VAF 19/38 reads (50%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as COSV99837832; called by muse, mutect2, varscan2
- SIK2 | c.2633C>T p.T878M | Missense Mutation (SNP) | VAF 17/31 reads (55%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.083); catalogued as rs772900316, COSV59253222; called by muse, mutect2, varscan2
- SIRT3 | c.1078G>A p.V360M | Missense Mutation (SNP) | VAF 26/40 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as rs772590751, COSV100291420; called by muse, mutect2, varscan2
- SKIV2L | c.913T>C p.F305L | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated (0.23); PolyPhen benign (0.009); catalogued as COSV100952615; called by muse, mutect2, varscan2
- SLC26A4 | c.1286C>T p.A429V | Missense Mutation (SNP) | VAF 25/48 reads (52%) | SIFT tolerated (0.83); PolyPhen benign (0.001); catalogued as rs753269996, CM118057, COSV99706624; called by muse, mutect2, varscan2
- SLC5A11 | c.1114G>T p.G372W | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100762691; called by muse, mutect2
- SMG1 | c.4375G>A p.A1459T | Missense Mutation (SNP) | VAF 14/25 reads (56%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.478); catalogued as COSV101245303; called by muse, mutect2, varscan2
- SOX6 | c.2081C>T p.P694L (on ENST00000528429 / NM_001145819.2; = p.P667L on NM_017508.3) | Missense Mutation (SNP) | VAF 42/105 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV57035417; called by muse, mutect2, varscan2
- ST3GAL5 | c.371T>G p.F124C (on ENST00000377332; = p.F164C on NM_003896.4) | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100088255; called by muse, mutect2, varscan2
- ST8SIA6 | c.753del p.A252Pfs*53 | Frame Shift Del (DEL) | VAF 8/19 reads (42%) | catalogued as rs758746672, COSV66468613; called by mutect2, varscan2
- STAB2 | c.7349del p.P2450Lfs*4 | Frame Shift Del (DEL) | VAF 23/50 reads (46%) | catalogued as COSV101186457; called by mutect2, pindel, varscan2
- STARD7 | c.821G>A p.R274H | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.973); catalogued as rs762860851, COSV100474519; called by muse, mutect2, varscan2
- STARD8 | c.2618del p.P873Qfs*28 | Frame Shift Del (DEL) | VAF 9/25 reads (36%) | catalogued as rs761897392; called by mutect2, pindel, varscan2
- SYNE1 | c.7768G>A p.G2590S (on ENST00000367255 / NM_182961.4; = p.G2597S on NM_033071.3) | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0.097); catalogued as rs367840064, COSV99555143; called by muse, mutect2, varscan2
- SYNPO2 | c.2188G>A p.G730R | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1168256741, COSV61108471; called by muse, mutect2, varscan2
- SYTL1 | c.971G>A p.R324Q (on ENST00000543823; = p.R312Q on NM_032872.3) | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.548); catalogued as rs761181092, COSV58872884; called by muse, mutect2, varscan2
- TEAD4 | c.638del p.P213Hfs*84 | Frame Shift Del (DEL) | VAF 13/25 reads (52%) | catalogued as COSV63282601; called by mutect2, pindel, varscan2
- TENM2 | c.3077G>A p.R1026Q (on ENST00000518659 / NM_001122679.2; = p.R794Q on NM_001080428.3) | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs777416334, COSV101318020, COSV69134319; called by muse, mutect2, varscan2
- TENT4B | c.727G>A p.E243K (on ENST00000561678 / NM_001365323.2; = p.E228K on NM_001040284.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT tolerated (0.23); PolyPhen benign (0.308); catalogued as rs978564621, COSV100665736; called by muse, mutect2, varscan2
- TMEM131L | c.688C>T p.Q230* | Nonsense Mutation (SNP) | VAF 16/25 reads (64%) | catalogued as COSV99546930; called by muse, mutect2, varscan2
- TMEM185A | c.718G>A p.A240T | Missense Mutation (SNP) | VAF 35/136 reads (26%) | SIFT tolerated (0.58); PolyPhen benign (0.001); catalogued as rs1265264531; called by muse, mutect2, varscan2
- TMEM217 | c.44C>T p.T15I | Missense Mutation (SNP) | VAF 17/24 reads (71%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); catalogued as rs1275383660, COSV100362476; called by muse, mutect2, varscan2
- TNS1 | c.2261G>A p.R754H | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs774313703, COSV50718732; called by mutect2, varscan2
- TP53 | c.289del p.V97Sfs*26 | Frame Shift Del (DEL) | VAF 14/35 reads (40%) | catalogued as CM045203, COSV53077329, COSV53837764; called by mutect2, pindel, varscan2
- TP73 | c.877C>A p.R293S | Missense Mutation (SNP) | VAF 14/24 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100600990, COSV100601379; called by muse, mutect2, varscan2
- TRIM46 | c.1406C>T p.T469M | Missense Mutation (SNP) | VAF 42/133 reads (32%) | SIFT tolerated (0.23); PolyPhen benign (0.031); catalogued as rs751531581, COSV100583627; called by muse, mutect2, varscan2
- TSGA10IP | c.1210C>T p.R404W | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs760323187, COSV101598386; called by muse, mutect2
- TSPOAP1 | c.4273C>T p.R1425* | Nonsense Mutation (SNP) | VAF 5/17 reads (29%) | catalogued as rs781330780, COSV99270220; called by muse, mutect2, varscan2
- TTC39C | c.1681G>A p.D561N (on ENST00000317571 / NM_001135993.2; = p.D500N on NM_153211.4) | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.125); catalogued as COSV100455196; called by muse, mutect2, varscan2
- TTLL4 | c.2774G>T p.G925V | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.898); catalogued as COSV99293069; called by muse, mutect2
- TTN | c.80218A>G p.I26740V (on ENST00000591111; = p.I19316V on NM_003319.4) | Missense Mutation (SNP) | VAF 11/24 reads (46%) | PolyPhen benign (0.003); catalogued as COSV100597378; called by muse, mutect2, varscan2
- UBA1 | c.3074G>A p.R1025Q | Missense Mutation (SNP) | VAF 22/38 reads (58%) | SIFT tolerated (0.1); PolyPhen benign (0.011); catalogued as rs147211127, COSV100255442; called by muse, mutect2, varscan2
- VANGL1 | c.1070G>A p.R357Q | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.3); catalogued as rs551165832, COSV100048883; called by muse, mutect2, varscan2
- VWA3B | c.3796G>A p.A1266T | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.011); catalogued as COSV101417773; called by mutect2, varscan2
- VWF | c.1253G>A p.C418Y | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99778196; called by muse, mutect2, varscan2
- WASHC2A | c.926C>T p.P309L | Missense Mutation (SNP) | VAF 28/88 reads (32%) | SIFT tolerated (0.2); PolyPhen benign (0.035); catalogued as rs1443058193; called by muse, mutect2, varscan2
- WDR24 | c.1184A>G p.H395R (on ENST00000248142; = p.H265R on NM_032259.4) | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.006); catalogued as rs917064151, COSV50196390; called by muse, mutect2
- WWC1 | c.1787C>T p.T596M | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs202122966, COSV99514391; called by muse, varscan2
- ZBTB24 | c.1726G>C p.V576L | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.027); catalogued as COSV100018318; called by muse, mutect2
- ZDBF2 | c.5184del p.K1728Nfs*5 | Frame Shift Del (DEL) | VAF 6/16 reads (38%) | catalogued as rs745875253; called by mutect2, varscan2
- ZER1 | c.1984C>T p.R662C | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.446); catalogued as rs1349440835, COSV52565150; called by muse, mutect2, varscan2
- ZNF133 | c.195del p.K65Nfs*122 (on ENST00000316358 / NM_001352454.2; = p.K65Nfs*121 on NM_003434.7 and 3 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 7/14 reads (50%) | catalogued as rs753775995, COSV60366352; called by mutect2, varscan2
- ZNF324B | c.1343C>T p.T448M | Missense Mutation (SNP) | VAF 18/31 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1199236275, COSV100351541; called by muse, mutect2, varscan2
- ZNF524 | c.392G>A p.R131H | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1343054947, COSV99684467; called by muse, mutect2, varscan2
- ZNF572 | c.874C>T p.R292W | Missense Mutation (SNP) | VAF 21/36 reads (58%) | SIFT deleterious (0); PolyPhen benign (0.289); catalogued as rs759158841, COSV100073835; called by muse, mutect2, varscan2
- ZNF655 | c.254A>C p.E85A | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.055); catalogued as COSV99401973; called by muse, mutect2
- ZNF668 | c.1333G>A p.A445T | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs1219943067, COSV100336409; called by muse, mutect2
- ZNF780A | c.1853G>A p.C618Y | Missense Mutation (SNP) | VAF 28/66 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs765756011, COSV100574980; called by muse, mutect2, varscan2
- ZNF831 | c.153del p.T52Lfs*4 | Frame Shift Del (DEL) | VAF 10/22 reads (45%) | catalogued as rs750329558; called by mutect2, varscan2
- ZSWIM8 | c.5216C>T p.T1739M (on ENST00000605216 / NM_001242487.2; = p.T1744M on NM_015037.3) | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.653); catalogued as rs750327939, COSV100013712; called by muse, mutect2
- ZXDA | c.869C>T p.T290M | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV62389104; called by muse, mutect2, varscan2
- ARFIP1 | c.713dup p.I239Hfs*3 (on ENST00000353617 / NM_001287432.1; = p.I207Hfs*3 on NM_014447.3 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 16/37 reads (43%) | called by mutect2, pindel, varscan2
- ARID1A | c.2272del p.Q758Rfs*75 | Frame Shift Del (DEL) | VAF 8/10 reads (80%) | called by mutect2, varscan2
- BAG6 | c.344del p.P115Lfs*53 | Frame Shift Del (DEL) | VAF 12/18 reads (67%) | called by mutect2, pindel, varscan2
- CCDC158 | c.610del p.I204Yfs*23 | Frame Shift Del (DEL) | VAF 11/36 reads (31%) | called by mutect2, pindel, varscan2
- CCDC40 | c.798dup p.S267Efs*2 | Frame Shift Ins (INS) | VAF 15/32 reads (47%) | called by mutect2, pindel, varscan2
- CD79A | c.390del p.R131Gfs*61 | Frame Shift Del (DEL) | VAF 11/23 reads (48%) | called by mutect2, pindel, varscan2
- COL24A1 | c.1688del p.P563Lfs*42 | Frame Shift Del (DEL) | VAF 4/23 reads (17%) | called by mutect2, pindel, varscan2
- DCC | c.3452del p.P1151Lfs*12 | Frame Shift Del (DEL) | VAF 8/19 reads (42%) | called by mutect2, pindel, varscan2
- DDC | c.1297del p.I433Sfs*98 | Frame Shift Del (DEL) | VAF 13/58 reads (22%) | called by mutect2, pindel, varscan2
- DPY19L3 | c.1949del p.G650Afs*15 | Frame Shift Del (DEL) | VAF 13/26 reads (50%) | called by mutect2, pindel, varscan2
- EPAS1 | c.475del p.S159Afs*12 | Frame Shift Del (DEL) | VAF 4/12 reads (33%) | called by mutect2, varscan2
- EVI2B | c.1088dup p.S364Ifs*6 | Frame Shift Ins (INS) | VAF 32/81 reads (40%) | called by mutect2, pindel, varscan2
- FILIP1 | c.638del p.K213Sfs*24 | Frame Shift Del (DEL) | VAF 4/10 reads (40%) | called by mutect2, varscan2
- FLNB | c.5165del p.P1722Lfs*7 | Frame Shift Del (DEL) | VAF 39/108 reads (36%) | called by mutect2, pindel, varscan2
- FOXA2 | c.664dup p.R222Pfs*17 (on ENST00000377115 / NM_153675.3; = p.R228Pfs*17 on NM_021784.5) | Frame Shift Ins (INS) | VAF 19/34 reads (56%) | called by mutect2, pindel, varscan2
- FOXP1 | c.447dup p.Q150Tfs*20 | Frame Shift Ins (INS) | VAF 50/70 reads (71%) | called by mutect2, pindel, varscan2
- GANAB | c.68del p.L23* | Frame Shift Del (DEL) | VAF 6/20 reads (30%) | called by mutect2, pindel, varscan2
- HINFP | c.775_776del p.L259Vfs*2 | Frame Shift Del (DEL) | VAF 12/32 reads (38%) | called by pindel, varscan2
- ICE1 | c.4768del p.E1590Kfs*16 | Frame Shift Del (DEL) | VAF 4/14 reads (29%) | called by mutect2, varscan2
- IL17RA | c.1387del p.A463Rfs*21 | Frame Shift Del (DEL) | VAF 7/23 reads (30%) | called by mutect2, pindel, varscan2
- IREB2 | c.696del p.F232Lfs*13 | Frame Shift Del (DEL) | VAF 6/31 reads (19%) | called by mutect2, pindel, varscan2
- JSRP1 | c.742_744del p.E248del | In Frame Del (DEL) | VAF 21/63 reads (33%) | called by mutect2, pindel, varscan2
- KIAA0232 | c.2353dup p.T785Nfs*3 | Frame Shift Ins (INS) | VAF 9/18 reads (50%) | called by mutect2, varscan2
- LACTB2 | c.634_636del p.Q212del | In Frame Del (DEL) | VAF 13/74 reads (18%) | called by pindel, varscan2
- LRBA | c.2240del p.L747* | Frame Shift Del (DEL) | VAF 14/39 reads (36%) | called by mutect2, pindel, varscan2
- LRRFIP2 | c.1162_1163del p.Q388Vfs*4 | Frame Shift Del (DEL) | VAF 22/73 reads (30%) | called by pindel, varscan2
- MALT1 | c.374del p.P125Qfs*3 | Frame Shift Del (DEL) | VAF 23/58 reads (40%) | called by mutect2, pindel, varscan2
- MAP3K1 | c.4199_4200dup p.G1401Lfs*22 | Frame Shift Ins (INS) | VAF 19/47 reads (40%) | called by mutect2, pindel, varscan2
- MED13 | c.4159del p.S1387Afs*15 | Frame Shift Del (DEL) | VAF 11/25 reads (44%) | called by mutect2, pindel, varscan2
- MEGF8 | c.7636del p.A2546Lfs*29 (on ENST00000251268 / NM_001271938.2; = p.A2479Lfs*29 on NM_001410.3) | Frame Shift Del (DEL) | VAF 8/16 reads (50%) | called by mutect2, pindel, varscan2
- MUC5AC | c.169del p.A57Rfs*7 | Frame Shift Del (DEL) | VAF 22/56 reads (39%) | called by mutect2, pindel, varscan2
- MYL10 | c.611del p.P204Qfs*42 | Frame Shift Del (DEL) | VAF 12/25 reads (48%) | called by mutect2, pindel, varscan2
- MYO9A | c.4264del p.Y1422Ifs*8 | Frame Shift Del (DEL) | VAF 16/41 reads (39%) | called by mutect2, varscan2
- NANOS2 | c.173del p.G58Afs*24 | Frame Shift Del (DEL) | VAF 19/45 reads (42%) | called by mutect2, pindel, varscan2
- NDST3 | c.2282dup p.F762Ifs*7 | Frame Shift Ins (INS) | VAF 15/37 reads (41%) | called by mutect2, pindel, varscan2
- NKAP | c.1203dup p.R402Sfs*13 | Frame Shift Ins (INS) | VAF 27/67 reads (40%) | called by mutect2, pindel, varscan2
- NPAP1 | c.2120dup p.A708Gfs*71 | Frame Shift Ins (INS) | VAF 8/23 reads (35%) | called by mutect2, pindel, varscan2
- NUCB2 | c.1200del p.K400Nfs*15 | Frame Shift Del (DEL) | VAF 18/44 reads (41%) | called by mutect2, varscan2
- NYAP1 | c.1714del p.V572Cfs*2 | Frame Shift Del (DEL) | VAF 6/31 reads (19%) | called by mutect2, pindel, varscan2
- PAK6 | c.1903del p.L635Wfs*19 | Frame Shift Del (DEL) | VAF 13/31 reads (42%) | called by mutect2, pindel, varscan2
- PANK2 | c.1298_1300del p.E433del (on ENST00000316562 / NM_153638.3; = p.E142del on NM_024960.6 and 1 other RefSeq transcript) | In Frame Del (DEL) | VAF 9/46 reads (20%) | called by pindel, varscan2
- POF1B | c.505dup p.T169Nfs*11 | Frame Shift Ins (INS) | VAF 20/61 reads (33%) | called by mutect2, pindel, varscan2
- PYHIN1 | c.1400dup p.N467Kfs*3 | Frame Shift Ins (INS) | VAF 17/62 reads (27%) | called by mutect2, pindel, varscan2
- RFLNA | c.624del p.S209Afs*64 (on ENST00000546355 / NM_001365156.1; = p.S128Afs*64 on NM_181709.4) | Frame Shift Del (DEL) | VAF 11/29 reads (38%) | called by mutect2, pindel, varscan2
- ROM1 | c.658dup p.H220Pfs*36 | Frame Shift Ins (INS) | VAF 10/25 reads (40%) | called by mutect2, pindel, varscan2
- SDK2 | c.4018C>T p.L1340F | Missense Mutation (SNP) | VAF 8/140 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); called by muse, mutect2
- SLC24A1 | c.2811del p.F937Lfs*12 | Frame Shift Del (DEL) | VAF 8/27 reads (30%) | called by mutect2, pindel, varscan2
- SLC26A7 | c.1445del p.N482Ifs*2 | Frame Shift Del (DEL) | VAF 44/90 reads (49%) | called by mutect2, pindel, varscan2
- SLC38A8 | c.906del p.F302Lfs*6 | Frame Shift Del (DEL) | VAF 7/23 reads (30%) | called by mutect2, pindel, varscan2
- SMAD7 | c.626del p.P209Lfs*115 | Frame Shift Del (DEL) | VAF 6/20 reads (30%) | called by mutect2, varscan2
- TAF4 | c.1358del p.P453Qfs*14 | Frame Shift Del (DEL) | VAF 4/12 reads (33%) | called by mutect2, varscan2
- TBCCD1 | c.323del p.K108Sfs*22 | Frame Shift Del (DEL) | VAF 11/27 reads (41%) | called by mutect2, pindel, varscan2
- TENM2 | c.4764del p.G1589Efs*18 (on ENST00000518659 / NM_001122679.2; = p.G1350Efs*18 on NM_001080428.3) | Frame Shift Del (DEL) | VAF 12/38 reads (32%) | called by mutect2, pindel, varscan2
- UBR1 | c.4564dup p.V1522Gfs*5 | Frame Shift Ins (INS) | VAF 11/26 reads (42%) | called by mutect2, pindel, varscan2
- USP34 | c.375del p.K125Nfs*10 | Frame Shift Del (DEL) | VAF 30/58 reads (52%) | called by mutect2, varscan2
- WDR4 | c.1178dup p.P394Afs*? (on ENST00000330317 / NM_033661.4; = p.P394Afs*37 on NM_018669.6 and 4 other RefSeq transcripts) | Frame Shift Ins (INS) | VAF 7/24 reads (29%) | called by mutect2, pindel, varscan2
- ZBTB20 | c.2075del p.P692Lfs*43 (on ENST00000474710 / NM_001164342.2; = p.P619Lfs*43 on NM_015642.6 and 4 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 19/38 reads (50%) | called by mutect2, pindel, varscan2
- ZFHX3 | c.2287del p.E763Sfs*61 | Frame Shift Del (DEL) | VAF 10/31 reads (32%) | called by mutect2, pindel
- ZNF687 | c.2687del p.G896Vfs*4 | Frame Shift Del (DEL) | VAF 20/56 reads (36%) | called by mutect2, pindel, varscan2
- ABHD2 | c.1108C>T p.L370= | Silent (SNP) | VAF 22/47 reads (47%) | catalogued as COSV100756174; called by muse, mutect2, varscan2
- AC011479.1 | c.78C>T p.R26= | Silent (SNP) | VAF 20/45 reads (44%) | catalogued as COSV100007472; called by muse, mutect2, varscan2
- ACO2 | c.2220C>T p.C740= | Silent (SNP) | VAF 17/36 reads (47%) | catalogued as COSV99347079; called by muse, mutect2, varscan2
- ACTA2 | c.972C>T p.P324= | Silent (SNP) | VAF 27/51 reads (53%) | catalogued as rs1204313866, COSV99826926; called by muse, mutect2, varscan2
- ARFGEF3 | c.2154C>T p.D718= | Silent (SNP) | VAF 10/25 reads (40%) | catalogued as rs749821517; called by muse, mutect2, varscan2
- ARHGAP30 | c.930T>C p.A310= | Silent (SNP) | VAF 8/30 reads (27%) | catalogued as COSV100920149; called by muse, mutect2, varscan2
- ARNTL | c.987G>A p.V329= (on ENST00000403290 / NM_001297719.2; = p.V328= on NM_001178.5 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 17/43 reads (40%) | catalogued as COSV100724590; called by muse, mutect2, varscan2
- ATP2B1 | c.2619C>T p.G873= | Silent (SNP) | VAF 6/12 reads (50%) | catalogued as rs775895156, COSV53806062; called by muse, mutect2
- BMT2 | c.516C>T p.G172= | Silent (SNP) | VAF 8/32 reads (25%) | catalogued as COSV99774456; called by muse, mutect2, varscan2
- CAPN15 | c.879G>A p.K293= | Silent (SNP) | VAF 6/19 reads (32%) | catalogued as COSV99562202; called by muse, mutect2
- CCDC158 | c.2508C>T p.R836= | Silent (SNP) | VAF 13/35 reads (37%) | catalogued as rs1244502898, COSV101187167; called by muse, mutect2, varscan2
- CCZ1B | c.717T>C p.D239= | Silent (SNP) | VAF 15/50 reads (30%) | catalogued as COSV100367755; called by muse, mutect2, varscan2
- CDC42EP3 | c.576G>A p.L192= | Silent (SNP) | VAF 10/23 reads (43%) | catalogued as rs1269347926, COSV99767781; called by muse, mutect2, varscan2
- CDH2 | c.576A>G p.S192= | Silent (SNP) | VAF 7/17 reads (41%) | catalogued as COSV99295897; called by muse, mutect2, varscan2
- CHD5 | c.5685G>A p.S1895= | Silent (SNP) | VAF 6/18 reads (33%) | catalogued as rs756618256, COSV52412613; called by muse, mutect2, varscan2
- CMIP | c.843G>A p.P281= (on ENST00000537098 / NM_198390.2; = p.P187= on NM_030629.3) | Silent (SNP) | VAF 20/41 reads (49%) | catalogued as rs1047620355, COSV101220856; called by muse, mutect2, varscan2
- CRTC1 | c.1821C>T p.L607= | Silent (SNP) | VAF 21/51 reads (41%) | catalogued as rs200281557, COSV100119137; called by muse, mutect2, varscan2
- CRX | c.465G>A p.T155= | Silent (SNP) | VAF 4/12 reads (33%) | catalogued as rs903901600, COSV99704369; called by muse, mutect2, varscan2
- CTRB1 | c.151C>T p.L51= | Silent (SNP) | VAF 17/36 reads (47%) | catalogued as rs1409849141, COSV100727085; called by muse, mutect2, varscan2
- CYP2S1 | c.1431C>A p.T477= | Silent (SNP) | VAF 11/29 reads (38%) | catalogued as COSV100027349; called by muse, mutect2, varscan2
- DGKK | c.1047T>C p.P349= | Silent (SNP) | VAF 14/23 reads (61%) | catalogued as COSV101052900; called by muse, mutect2, varscan2
- DIDO1 | c.3915G>A p.S1305= | Silent (SNP) | VAF 38/60 reads (63%) | catalogued as rs764398815, COSV99824964; called by muse, mutect2, varscan2
- DISP3 | c.2739G>A p.K913= | Silent (SNP) | VAF 16/35 reads (46%) | catalogued as COSV99607551, COSV99609397; called by muse, mutect2, varscan2
- DLST | c.387T>C p.P129= | Silent (SNP) | VAF 4/42 reads (10%) | catalogued as COSV99471809; called by muse, mutect2
- DOK7 | c.870G>A p.S290= | Silent (SNP) | VAF 14/26 reads (54%) | catalogued as rs149019681; called by muse, mutect2, varscan2
- EBF2 | c.1548C>T p.T516= | Silent (SNP) | VAF 11/32 reads (34%) | catalogued as rs371578362; called by muse, mutect2, varscan2
- ELOA2 | c.960A>G p.L320= | Silent (SNP) | VAF 5/39 reads (13%) | catalogued as rs375002079; called by muse, mutect2, varscan2
- FANCG | c.834C>T p.A278= | Silent (SNP) | VAF 16/35 reads (46%) | catalogued as rs1466753644, COSV100734113; called by muse, mutect2, varscan2
- FLG | c.5166C>T p.S1722= | Silent (SNP) | VAF 57/159 reads (36%) | catalogued as rs781501564, COSV64238490; called by muse, mutect2, varscan2
- FOXN1 | c.1428C>T p.D476= | Silent (SNP) | VAF 21/56 reads (38%) | catalogued as rs745515677, COSV99881012; called by muse, mutect2, varscan2
- GLIS3 | c.1182C>T p.N394= | Silent (SNP) | VAF 12/24 reads (50%) | catalogued as COSV100173384; called by muse, mutect2, varscan2
- HK3 | c.1176C>T p.C392= | Silent (SNP) | VAF 5/17 reads (29%) | catalogued as COSV99457964; called by muse, mutect2, varscan2
- IPO4 | c.3162G>A p.Q1054= | Silent (SNP) | VAF 20/50 reads (40%) | catalogued as COSV100268887; called by muse, mutect2, varscan2
- JMJD7-PLA2G4B | c.426G>A p.L142= | Silent (SNP) | VAF 4/14 reads (29%) | catalogued as COSV100583705; called by muse, mutect2
- KCNT1 | c.804C>T p.C268= (on ENST00000488444; = p.C287= on NM_020822.3) | Silent (SNP) | VAF 15/25 reads (60%) | catalogued as rs750884338, COSV99705106, COSV99706815; ClinVar: likely benign; called by muse, mutect2, varscan2
- KIF3B | c.2178C>T p.S726= | Silent (SNP) | VAF 11/26 reads (42%) | catalogued as rs769861420, COSV100996330; called by muse, mutect2, varscan2
- KRTAP10-6 | c.645G>A p.Q215= | Silent (SNP) | VAF 8/106 reads (8%) | catalogued as COSV100552142; called by muse, mutect2
- LPIN3 | c.585G>A p.L195= | Silent (SNP) | VAF 6/25 reads (24%) | catalogued as rs1306110444, COSV100952905; called by muse, mutect2, varscan2
- LPIN3 | c.1614C>T p.A538= | Silent (SNP) | VAF 15/33 reads (45%) | catalogued as rs755888769, COSV100952906; called by muse, mutect2, varscan2
- LRP4 | c.3159C>T p.F1053= | Silent (SNP) | VAF 16/32 reads (50%) | catalogued as rs369751423; called by muse, mutect2, varscan2
- LTBP1 | c.3975G>A p.G1325= (on ENST00000404816 / NM_206943.4; = p.G999= on NM_000627.4) | Silent (SNP) | VAF 22/44 reads (50%) | catalogued as COSV99697827; called by muse, mutect2, varscan2
- MC2R | c.139C>T p.L47= | Silent (SNP) | VAF 6/32 reads (19%) | catalogued as COSV100562905; called by muse, mutect2
- MLH1 | c.900C>A p.P300= | Silent (SNP) | VAF 25/44 reads (57%) | catalogued as rs1256030071, COSV99212341; called by muse, mutect2, varscan2
- MUC5B | c.10149C>T p.T3383= | Silent (SNP) | VAF 37/75 reads (49%) | catalogued as rs1464196765, COSV101500062; called by muse, mutect2, varscan2
- OR6C65 | c.547C>T p.L183= | Silent (SNP) | VAF 16/38 reads (42%) | catalogued as COSV65568987; called by muse, mutect2, varscan2
- PCDHB5 | c.1338C>T p.N446= | Silent (SNP) | VAF 6/95 reads (6%) | catalogued as rs781959722, COSV50647937; called by muse, mutect2
- PCDHB8 | c.1479G>A p.P493= | Silent (SNP) | VAF 15/117 reads (13%) | catalogued as COSV50757220; called by muse, mutect2, varscan2
- PFAS | c.3801A>C p.T1267= | Silent (SNP) | VAF 3/24 reads (13%) | catalogued as COSV100118790; called by muse, mutect2
- PHF3 | c.4308A>G p.P1436= | Silent (SNP) | VAF 6/17 reads (35%) | catalogued as COSV100012947; called by muse, mutect2, varscan2
- PRRG3 | c.93C>T p.T31= | Silent (SNP) | VAF 17/41 reads (41%) | catalogued as COSV100948557; called by muse, mutect2, varscan2
- PTCHD3 | c.1203A>G p.S401= | Silent (SNP) | VAF 13/28 reads (46%) | catalogued as COSV71256728; called by muse, mutect2, varscan2
- PTCHD3 | c.912C>T p.Y304= | Silent (SNP) | VAF 9/28 reads (32%) | catalogued as COSV101438839; called by muse, mutect2, varscan2
- PTCHD3 | c.717G>A p.L239= | Silent (SNP) | VAF 18/32 reads (56%) | catalogued as COSV101438840; called by muse, mutect2, varscan2
- PTPN23 | c.4719C>T p.P1573= | Silent (SNP) | VAF 19/28 reads (68%) | catalogued as COSV55546578, COSV99650248; called by muse, mutect2, varscan2
- SEL1L3 | c.2151C>T p.Y717= | Silent (SNP) | VAF 10/26 reads (38%) | catalogued as rs374120533; called by muse, mutect2, varscan2
- SIK3 | c.3066C>A p.T1022= (on ENST00000445177 / NM_001366686.2; = p.T980= on NM_025164.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 35/61 reads (57%) | catalogued as COSV99407314; called by muse, mutect2, varscan2
- SIK3 | c.804C>T p.R268= (on ENST00000445177 / NM_001366686.2; = p.R274= on NM_025164.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 9/18 reads (50%) | catalogued as rs781741381, COSV52613629; called by muse, mutect2, varscan2
- SPATC1 | c.1746C>T p.H582= | Silent (SNP) | VAF 17/24 reads (71%) | catalogued as rs1244507069, COSV101084760; called by muse, mutect2, varscan2
- SPSB4 | c.594C>T p.G198= | Silent (SNP) | VAF 15/45 reads (33%) | catalogued as COSV60144612; called by muse, mutect2, varscan2
- SPTA1 | c.1290T>C p.D430= | Silent (SNP) | VAF 9/32 reads (28%) | catalogued as COSV100934437; called by muse, mutect2, varscan2
- TBL3 | c.639C>T p.S213= | Silent (SNP) | VAF 7/26 reads (27%) | catalogued as rs544086040, COSV100224723; called by muse, mutect2, varscan2
- TEP1 | c.4131G>A p.L1377= | Silent (SNP) | VAF 23/44 reads (52%) | catalogued as COSV99401775; called by muse, mutect2, varscan2
- TIMP4 | c.40T>C p.L14= | Silent (SNP) | VAF 5/15 reads (33%) | catalogued as COSV99825942; called by muse, mutect2, varscan2
- TMEM120B | c.264C>T p.D88= | Silent (SNP) | VAF 7/23 reads (30%) | catalogued as rs367697914; called by muse, mutect2, varscan2
- TMPRSS6 | c.570C>T p.P190= | Silent (SNP) | VAF 9/31 reads (29%) | catalogued as rs773297269, COSV60977160; called by muse, mutect2, varscan2
- TNXB | c.7818C>T p.S2606= (on ENST00000647633; = p.S2359= on NM_019105.8 and 1 other RefSeq transcript) | Silent (SNP) | VAF 29/72 reads (40%) | catalogued as rs548923920, COSV64473505; called by muse, varscan2
- TSFM | c.738A>G p.S246= (on ENST00000323833 / NM_001172696.2; = p.S225= on NM_005726.6) | Silent (SNP) | VAF 23/51 reads (45%) | catalogued as COSV99142189; called by muse, mutect2, varscan2
- UHRF2 | c.2274G>A p.Q758= | Silent (SNP) | VAF 26/47 reads (55%) | catalogued as COSV99436209; called by muse, mutect2, varscan2
- XIRP1 | c.5418C>T p.H1806= | Silent (SNP) | VAF 24/50 reads (48%) | catalogued as rs780300982, COSV61136935; called by muse, mutect2, varscan2
- XIRP2 | c.267C>T p.D89= (on ENST00000628543; = p.D264= on NM_152381.6) | Silent (SNP) | VAF 9/22 reads (41%) | catalogued as rs575905650, COSV54679664; called by muse, mutect2, varscan2
- ZNF470 | c.462A>C p.T154= | Silent (SNP) | VAF 6/12 reads (50%) | catalogued as COSV100401106; called by muse, mutect2, varscan2
- ZNF672 | c.1266C>T p.T422= | Silent (SNP) | VAF 16/43 reads (37%) | catalogued as rs958677691, COSV100129075; called by muse, mutect2, varscan2
- AC092718.9 | chr16:81148284 G>A | 5'Flank (SNP) | VAF 9/14 reads (64%) | called by muse, mutect2, varscan2
- PCCA | c.1285-1358C>T | Intron (SNP) | VAF 4/19 reads (21%) | catalogued as rs751173649, COSV66193163; called by muse, mutect2, varscan2
- TMEM167B | chr1:109100224 G>T | 3'Flank (SNP) | VAF 17/39 reads (44%) | catalogued as rs746615962; called by muse, mutect2, varscan2
- TRAC | c.*133del | 3'UTR (DEL) | VAF 32/72 reads (44%) | catalogued as rs747854238; called by mutect2, pindel, varscan2
